Surgical pathology report (de-identified scan), TCGA case TCGA-IG-A3QL, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Asterand, specimen TCGA-IG-A3QL-01A (Primary Tumor).

Procurement Date Laterality: Distal

Path Report: ESOPHAGUS TISSUE CHECKLIST

Specimen type: Excision of tumor

Tumor site: Esophagus

Tumor size: 2 x 1.5 x 0.3 cm

Histologic type: Squamous cell carcinoma, keratinizing

Histologic grade: Moderately differentiated

Tumor extent: Muscularis propria

Lymph nodes: 0/7 positive for metastasis (Regional 0/7)

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

107-0-3

carcinoma, Squamous cell, Keratinizing

8071/3

Site: esophagus, distal third

C15.5

2-28-12 RD

Reviewer (signature)	Date Reviewed: 2/21/12	

Source: NCI Genomic Data Commons file 832d4f25-00d3-44a0-9c95-e6e4652868f0 (TCGA-IG-A3QL.DF33987A-2A2D-48E4-BF78-9CFD30D19D0F.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).